Somatic mutation profile of tumor specimen TCGA-EL-A3GU-01A (aliquot TCGA-EL-A3GU-01A-11D-A21A-08) from TCGA case TCGA-EL-A3GU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 72.9 years (26,632 days).
Specimen TCGA-EL-A3GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9846693-a8da-40a6-ad84-ef2836934963.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GU-11A (Solid Tissue Normal), aliquot TCGA-EL-A3GU-11A-21D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a8775cf-5af2-4084-bf1f-81fd23a5739d

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ALDH5A1 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV62373735; called by muse, mutect2, varscan2
- BCL9 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52344872, COSV52351622; called by muse, mutect2, varscan2
- BSPRY | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV65242768; called by muse, mutect2, varscan2
- CALCR | c.1330G>A p.A444T (on ENST00000649521 / NM_001164737.2; = p.A428T on NM_001742.4) | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1384027930, COSV64008506; called by muse, mutect2, varscan2
- GALT | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV66592976; called by muse, mutect2, varscan2
- HNF4A | c.601T>A p.W201R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57383662; called by muse, mutect2
- MKLN1 | c.352A>T p.K118* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV61761066; called by muse, mutect2, varscan2
- MSI1 | c.549A>C p.K183N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57456491; called by muse, mutect2, varscan2
- NIN | c.6079G>A p.G2027R (on ENST00000382041 / NM_182946.1; = p.G1314R on NM_016350.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1472178080, COSV55392122; called by muse, mutect2, varscan2
- PDHA2 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355426428, COSV54777347; called by muse, mutect2
- SETD5 | c.4220C>T p.A1407V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs779227220, COSV56711549; called by muse, mutect2, varscan2
- JMJD1C | c.3491del p.P1164Qfs*13 | Frame Shift Del (DEL) | VAF 80/271 reads (30%) | called by mutect2, pindel, varscan2
- MACF1 | c.19640G>A p.R6547K (on ENST00000372915; = p.R4592K on NM_012090.5) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- SDCCAG8 | c.906_927del p.M302Ifs*7 | Frame Shift Del (DEL) | VAF 61/235 reads (26%) | called by mutect2, pindel, varscan2
- COL5A1 | c.5097C>T p.N1699= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65669541; called by mutect2, varscan2
- MAGED2 | c.1632T>C p.S544= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54497996; called by muse, mutect2, varscan2
- MPDZ | c.4671A>G p.K1557= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV59918609; called by muse, mutect2, varscan2
- NAV1 | c.4482G>A p.V1494= | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as COSV55218321; called by muse, mutect2
- NONO | c.261G>A p.E87= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as rs1379364784, COSV99338587; called by muse, mutect2
